Somatic mutation profile of tumor specimen TCGA-UZ-A9PX-01A (aliquot TCGA-UZ-A9PX-01A-11D-A42J-10) from TCGA case TCGA-UZ-A9PX, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-UZ-A9PX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39c448a3-063e-45c5-a2e8-7bcf8df9414f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PX-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PX-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26eee9d9-3e67-4663-80fc-aad60841cfec

The open-access MAF lists 110 somatic variants for this specimen: 85 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 24, Frame Shift Del 7, Frame Shift Ins 4, Nonsense Mutation 2, In Frame Del 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS2 | c.204del p.E68Dfs*19 | Frame Shift Del (DEL) | VAF 31/93 reads (33%) | catalogued as COSV53624711; called by mutect2, pindel, varscan2
- ACVR1B | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 69/105 reads (66%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV99231704; called by muse, mutect2, varscan2
- ADSS1 | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781702955, COSV58277263; called by muse, mutect2, varscan2
- ALPK2 | c.4513C>G p.P1505A | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV100864696, COSV64497048; called by muse, mutect2, varscan2
- AP5M1 | c.919T>A p.S307T | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV99841306; called by muse, mutect2, varscan2
- APOB | c.3451G>A p.D1151N | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV51940281; called by muse, mutect2, varscan2
- AQP6 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1365188304, COSV100210228, COSV59645994; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1402T>C p.Y468H | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.35); catalogued as COSV99369560; called by muse, mutect2, varscan2
- BCL2L13 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100456366; called by muse, mutect2, varscan2
- CAB39 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs779895273, COSV51474895; called by muse, mutect2, varscan2
- CARNS1 | c.1953G>T p.E651D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.013); catalogued as COSV100322166; called by muse, mutect2, varscan2
- CCDC171 | c.1672G>C p.A558P | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99901567; called by muse, mutect2, varscan2
- CIZ1 | c.1976G>T p.C659F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99477038; called by muse, mutect2
- CLCN5 | c.713A>G p.K238R | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.718); catalogued as COSV100260329; called by muse, mutect2, varscan2
- CLN3 | c.545G>T p.G182V (on ENST00000360019 / NM_001286104.2; = p.G206V on NM_000086.2) | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100343579; called by muse, mutect2, varscan2
- CTNNB1 | c.776T>A p.L259H | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100846399; called by muse, mutect2, varscan2
- CYP4F2 | c.334A>T p.N112Y | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV99171110; called by muse, mutect2, varscan2
- DDX5 | c.1358T>A p.V453E | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV56747738, COSV99858180; called by muse, mutect2, varscan2
- DEPDC1B | c.1046G>A p.G349D | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV99409792; called by muse, mutect2, varscan2
- ELK1 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV99902256; called by muse, mutect2, varscan2
- ERC1 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.206); catalogued as rs1466844791, COSV100706520, COSV61691997; called by muse, mutect2, varscan2
- ERMAP | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV100072342; called by muse, mutect2, varscan2
- F2 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV100319635; called by muse, mutect2, varscan2
- FAM160B1 | c.1438C>A p.Q480K | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as COSV100985550; called by muse, mutect2, varscan2
- GMEB1 | c.1019C>A p.T340K | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99603387; called by muse, mutect2, varscan2
- GNB5 | c.794T>C p.V265A (on ENST00000261837 / NM_016194.4; = p.V223A on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99953566; called by muse, mutect2, varscan2
- GRK3 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV100151870; called by muse, mutect2, varscan2
- GRM4 | c.1552T>G p.S518A | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100946692; called by muse, mutect2, varscan2
- HERC2 | c.13115C>T p.S4372L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs371676185; called by muse, mutect2, varscan2
- HIPK2 | c.1462A>G p.S488G | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100702448; called by muse, mutect2, varscan2
- HSPB8 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs762887808, COSV56137914; called by muse, mutect2, varscan2
- ITSN2 | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.159); catalogued as COSV100743996; called by muse, mutect2, varscan2
- KLB | c.558C>A p.N186K | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as COSV99962389; called by muse, mutect2, varscan2
- KLHL20 | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99268587; called by muse, mutect2, varscan2
- LRIG2 | c.1222G>T p.G408C | Missense Mutation (SNP) | VAF 138/307 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100743589; called by muse, mutect2, varscan2
- LSM14B | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99444593; called by muse, mutect2, varscan2
- MAG | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1276359720, COSV100727989; called by muse, mutect2, varscan2
- MKI67 | c.5569del p.I1857Yfs*30 | Frame Shift Del (DEL) | VAF 39/109 reads (36%) | catalogued as rs866533107; called by mutect2, pindel, varscan2
- MTIF2 | c.1037A>C p.E346A | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as COSV99709262; called by muse, mutect2, varscan2
- MYOC | c.364G>C p.G122R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV99231645; called by muse, mutect2, varscan2
- NAA10 | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100892461; called by muse, mutect2, varscan2
- NFU1 | c.193G>A p.D65N (on ENST00000410022 / NM_001002755.4; = p.D41N on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as COSV100361300; called by muse, mutect2, varscan2
- NFYC | c.714G>C p.Q238H | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as COSV100438639, COSV58127648; called by muse, mutect2, varscan2
- NOS2 | c.1567C>G p.L523V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.497); catalogued as COSV100569821; called by muse, varscan2
- OR2F1 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231321; called by muse, mutect2, varscan2
- OR52B6 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs375173605; called by muse, mutect2, varscan2
- OR8D2 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs1452683177, COSV100659069; called by muse, mutect2, varscan2
- PRKG2 | c.119A>C p.K40T | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV100020302; called by muse, mutect2, varscan2
- PRUNE2 | c.4951A>G p.T1651A | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100944969; called by muse, mutect2, varscan2
- RFX7 | c.3016C>A p.P1006T (on ENST00000559447 / NM_001368074.1; = p.P1103T on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100429175, COSV57966406; called by muse, mutect2
- RNF185 | c.518T>A p.F173Y | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.827); catalogued as COSV99839880; called by muse, mutect2, varscan2
- RNF20 | c.1006A>G p.K336E | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1352755281, COSV101206563; called by muse, mutect2, varscan2
- RYR3 | c.11482C>A p.Q3828K (on ENST00000389232; = p.Q3829K on NM_001036.6) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV101213595; called by muse, mutect2, varscan2
- SAP30 | c.372C>G p.N124K | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99633210; called by muse, mutect2, varscan2
- SEC31A | c.2530A>G p.I844V (on ENST00000355196 / NM_001318120.1; = p.I805V on NM_016211.4) | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs375945567; called by muse, mutect2, varscan2
- SHOC1 | c.1843C>G p.P615A | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.421); catalogued as COSV100597936; called by muse, mutect2, varscan2
- SLC25A19 | c.713A>C p.D238A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100237604; called by muse, mutect2, varscan2
- SLC25A3 | c.791T>C p.V264A (on ENST00000228318 / NM_005888.3; = p.V263A on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV99499499; called by muse, mutect2, varscan2
- SPSB2 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99222972; called by muse, mutect2, varscan2
- SSBP1 | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV54681640; called by muse, mutect2
- ST8SIA4 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 32/78 reads (41%) | PolyPhen benign (0); catalogued as COSV99185431; called by muse, mutect2, varscan2
- TCN2 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV99308719, COSV99308908; called by muse, mutect2, varscan2
- TERF2IP | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100265763; called by muse, mutect2, varscan2
- THBS4 | c.2479C>T p.R827* | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | catalogued as rs767609886, COSV100644223, COSV63471493; called by muse, mutect2, varscan2
- TMF1 | c.1338T>G p.D446E | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV101275454; called by muse, mutect2, varscan2
- TNFRSF19 | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.178); catalogued as COSV99947586; called by muse, mutect2, varscan2
- TRIO | c.4655C>A p.P1552H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100710757; called by muse, mutect2, varscan2
- TTC21B | c.3805+2T>A p.X1269_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99692671; called by muse, mutect2, varscan2
- TYW5 | c.64C>A p.H22N | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs764378011, COSV99705314; called by mutect2, varscan2
- UBAP2L | c.1175T>C p.M392T | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99671949; called by muse, mutect2, varscan2
- UNC13A | c.4567G>A p.V1523I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV99409168; called by muse, mutect2, varscan2
- ZDHHC16 | c.608T>C p.F203S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100513033; called by muse, varscan2
- ZMYM6 | c.2057T>G p.L686* | Nonsense Mutation (SNP) | VAF 43/90 reads (48%) | catalogued as COSV100593287; called by muse, mutect2, varscan2
- ZNF3 | c.871A>G p.K291E | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99447360; called by muse, mutect2, varscan2
- ARHGAP22 | c.1045_1047del p.F349del | In Frame Del (DEL) | VAF 30/83 reads (36%) | called by mutect2, pindel, varscan2
- CRYBG3 | c.6078dup p.H2027Sfs*2 | Frame Shift Ins (INS) | VAF 52/144 reads (36%) | called by mutect2, pindel, varscan2
- DYNC1I2 | c.592_593dup p.N199Kfs*11 | Frame Shift Ins (INS) | VAF 57/151 reads (38%) | called by mutect2, pindel, varscan2
- GOLGA4 | c.5682_5685dup p.P1896* | Frame Shift Ins (INS) | VAF 82/192 reads (43%) | called by mutect2, varscan2
- KL | c.942del p.E315Nfs*10 | Frame Shift Del (DEL) | VAF 54/160 reads (34%) | called by mutect2, pindel, varscan2
- MYOF | c.5658del p.I1887Yfs*16 | Frame Shift Del (DEL) | VAF 29/80 reads (36%) | called by mutect2, varscan2
- TNRC18 | c.6973_6982del p.P2325Rfs*35 | Frame Shift Del (DEL) | VAF 56/133 reads (42%) | called by mutect2, pindel, varscan2
- TSHR | c.2204del p.M735Rfs*7 | Frame Shift Del (DEL) | VAF 39/104 reads (38%) | called by mutect2, varscan2
- TTLL13P | c.355_358del p.T119Cfs*16 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | called by mutect2, pindel, varscan2
- WDFY3 | c.2384_2385dup p.S796Lfs*36 | Frame Shift Ins (INS) | VAF 72/203 reads (35%) | called by mutect2, pindel, varscan2
- ZDHHC16 | c.596_598del p.Y199del | In Frame Del (DEL) | VAF 18/48 reads (38%) | called by pindel, varscan2
- ADAMTS10 | c.963C>T p.I321= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs1053681963, COSV54352899; called by muse, mutect2, varscan2
- CFAP70 | c.2121G>A p.L707= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV100160933; called by muse, mutect2, varscan2
- DCC | c.2304C>T p.Y768= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs141228869, COSV100502059; called by muse, mutect2, varscan2
- DCLRE1B | c.852C>T p.A284= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV100849828; called by muse, mutect2, varscan2
- DCP1B | c.1443T>A p.A481= | Silent (SNP) | VAF 49/83 reads (59%) | catalogued as COSV99767791; called by muse, mutect2, varscan2
- DZIP1 | c.495G>A p.K165= | Silent (SNP) | VAF 35/52 reads (67%) | catalogued as rs1024109243, COSV100714160; called by muse, mutect2, varscan2
- KIAA1109 | c.2952T>A p.T984= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV52679689, COSV99169633; called by muse, mutect2, varscan2
- KLF1 | c.498G>T p.L166= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV99322472; called by muse, mutect2, varscan2
- LETM1 | c.783C>A p.A261= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV100245558; called by muse, mutect2, varscan2
- LTV1 | c.759T>C p.N253= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV100849611; called by muse, mutect2, varscan2
- MAP3K1 | c.3618T>C p.P1206= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV101267084; called by muse, mutect2, varscan2
- PPARGC1A | c.270A>T p.A90= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs1390786408, COSV99338372; called by muse, mutect2, varscan2
- PPFIA2 | c.1668G>T p.R556= | Silent (SNP) | VAF 50/78 reads (64%) | catalogued as COSV100334682; called by muse, mutect2, varscan2
- PTCHD1 | c.171G>A p.A57= | Silent (SNP) | VAF 40/45 reads (89%) | catalogued as rs753665613, COSV101037471; called by muse, mutect2, varscan2
- PTGS1 | c.192C>G p.S64= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99792945, COSV99793404; called by muse, varscan2
- RBM15B | c.792C>A p.R264= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100082277; called by muse, mutect2
- SLC25A42 | c.486C>A p.T162= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100588180; called by muse, mutect2, varscan2
- SMC1B | c.27G>C p.V9= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as COSV100663414; called by muse, mutect2, varscan2
- SNURF | c.66A>G p.E22= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV100578462, COSV57601298; called by muse, mutect2, varscan2
- SPDEF | c.441C>A p.P147= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100927823; called by muse, mutect2, varscan2
- SVEP1 | c.2478G>A p.L826= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV57044032; called by muse, mutect2, varscan2
- UTP18 | c.1173T>C p.S391= | Silent (SNP) | VAF 83/336 reads (25%) | catalogued as COSV99834890; called by muse, mutect2, varscan2
- WDR93 | c.786T>C p.P262= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as COSV99175760; called by muse, mutect2, varscan2
- ZDHHC16 | c.609C>T p.F203= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100513034; called by muse, varscan2
- C6orf223 | n.247T>C | RNA (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100350509; called by muse, mutect2, varscan2
